Somatic mutation profile of tumor specimen BA2520D (aliquot aq-BA2520D) from BEATAML1.0 case 2400, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.4 years (29,380 days).
Specimen BA2520D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a4ab6d4-3115-4e82-9b0c-6811aa3fe2b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2888D (Solid Tissue Normal), aliquot aq-BA2888D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4a003d0-5013-4872-b7ee-ef57853d77d2

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRSK2 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs373413941; called by muse, mutect2, varscan2
- CKM | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs961557355; called by muse, mutect2
- HABP4 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1229347620; called by muse, mutect2
- INHA | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2
- ITGAD | c.1565C>A p.A522E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2
- KIAA1210 | c.2323G>T p.D775Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2
- TGM1 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF827 | c.1470G>T p.R490S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- HECTD4 | c.1908A>G p.R636= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- LMOD2 | c.1588C>A p.R530= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV71755605; called by muse, mutect2
- OSCP1 | c.840A>G p.S280= (on ENST00000356637 / NM_001330493.1; = p.S270= on NM_145047.5) | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs1435623475; called by muse, mutect2, varscan2
- PRR23B | c.354G>T p.S118= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV61493585; called by muse, mutect2
- IRAG2 | c.3755-222A>G | Intron (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
